Gene-level copy-number profile of tumor specimen TCGA-HD-A6HZ-01A from TCGA case TCGA-HD-A6HZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 79.5 years (29,045 days).
Specimen TCGA-HD-A6HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8e3ed0fb-240d-4eac-bd51-86f5e8ea2a26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-A6HZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b0a3462-33e9-40ca-bd6a-5fd89d0893a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 404; copy number 2: 25,153; copy number 3: 22,177; copy number 4: 8,889; copy number 5: 762; copy number 6: 601; copy number 7: 697; copy number 8: 37; copy number 9: 880; copy number 12: 1; copy number 13: 14; copy number 15: 12; copy number 24: 124.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-A6HZ-01A-12D-A31K-01): tumor purity 0.34, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:85,968,999–92,873,682, 61 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,128 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:69,055,838–70,354,734, 15 genes, copy number 6 (within-gene range 3–6): LINC01707, LINC02791, LINC01758, AL359894.1, LRRC7, SGO1P1, AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C.
- chr2:107,254,691–112,346,258, 127 genes, copy number 6 (broad region; genes not listed).
- chr2:112,773,925–113,962,596, 48 genes, copy number 6: IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3.
- chr2:114,420,125–124,989,325, 102 genes, copy number 6 (broad region; genes not listed).
- chr2:161,424,332–161,985,282, 1 gene, copy number 6 (within-gene range 2–6): SLC4A10.
- chr2:161,500,885–164,352,223, 25 genes, copy number 6: AHCTF1P1, AC092654.1, AC062022.1, AC062022.2, KRT18P46, RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P.
- chr2:173,705,948–176,930,090, 79 genes, copy number 5 (broad region; genes not listed).
- chr2:184,378,975–184,379,044, 1 gene, copy number 5: MIR548AE1.
- chr3:174,438,573–175,810,548, 1 gene, copy number 5 (within-gene range 4–5): NAALADL2.
- chr3:175,059,361–177,011,067, 21 genes, copy number 5: EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15.
- chr3:177,037,405–177,047,923, 1 gene, copy number 5: TBL1XR1-AS1.
- chr5:38,025,568–39,103,677, 20 genes, copy number 5 (within-gene range 3–5): LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1.
- chr5:40,998,017–41,587,787, 4 genes, copy number 8: MROH2B, C6, PLCXD3, AC008817.1.
- chr5:50,858,760–51,964,445, 19 genes, copy number 6: AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1.
- chr5:54,643,557–60,522,120, 95 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr5:62,776,877–67,169,595, 48 genes, copy number 5–8 (within-gene range 1–8): ISCA1P1, AC113420.1, AC025445.1, AC008558.1, HTR1A, AC122707.1, RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2, SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1.
- chr7:53,187,388–56,229,782, 71 genes, copy number 5 (broad region; genes not listed).
- chr7:67,278,714–67,770,468, 10 genes, copy number 5: SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1.
- chr7:81,946,444–83,162,930, 6 genes, copy number 5 (within-gene range 2–5): CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235.
- chr7:83,955,777–90,311,063, 60 genes, copy number 7 (within-gene range 4–7): SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2.
- chr7:91,030,149–93,928,610, 51 genes, copy number 6 (within-gene range 3–6): AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11.
- chr7:94,907,202–95,296,415, 1 gene, copy number 7 (within-gene range 3–7): PPP1R9A.
- chr7:95,035,731–104,208,047, 283 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:63,136,223–63,693,249, 11 genes, copy number 5: AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2.
- chr8:63,703,077–63,813,937, 2 genes, copy number 5: AC069133.1, LINC01289.
- chr8:87,540,835–87,755,718, 1 gene, copy number 7 (within-gene range 3–7): AF121898.1.
- chr8:87,598,462–88,328,025, 6 genes, copy number 7 (within-gene range 2–7): IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16.
- chr8:98,782,055–142,614,479, 575 genes, copy number 6–7 (broad region; genes not listed).
- chr10:46,578,217–48,274,696, 46 genes, copy number 5: SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20, GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP, FRMPD2, AC074325.1.
- chr10:126,988,095–127,026,507, 2 genes, copy number 5: AL359094.1, AL359094.2.
- chr12:66,767–42,590,355, 915 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr12:61,600,067–71,441,898, 208 genes, copy number 7–24 (within-gene range 3–24) (broad region; genes not listed).
- chr14:18,333,726–22,482,959, 273 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
